FM case AD13302 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/32495f4a-ca75-4cdc-8d0c-34c43030fe94

Male, 81.9 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
